Gene-level copy-number profile of tumor specimen TCGA-R8-A6MK-01A from TCGA case TCGA-R8-A6MK, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 40.3 years (14,716 days).
Specimen TCGA-R8-A6MK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.5c9d3e35-cb73-4217-a929-4ec33a2112ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R8-A6MK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6c00e77-a3a9-479d-94ea-6ed699779ef6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,659; copy number 2: 52,037; copy number 3: 39; copy number 5: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R8-A6MK-01A-11D-A32A-01): tumor purity 0.71, ploidy 3.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 69 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,273,587–38,318,861, 7 genes, copy number 5: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr14:22,123,318–22,509,406, 62 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,238. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
